Somatic mutation profile of tumor specimen TCGA-G3-A25Y-01A (aliquot TCGA-G3-A25Y-01A-11D-A16V-10) from TCGA case TCGA-G3-A25Y, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 52.2 years (19,055 days).
Specimen TCGA-G3-A25Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) afe9f2f0-ab0e-4409-b8af-a561f2a5ba36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G3-A25Y-10A (Blood Derived Normal), aliquot TCGA-G3-A25Y-10A-01D-A16V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0f8d118-2990-43d7-90dc-4aa46d98b460

The open-access MAF lists 88 somatic variants for this specimen: 71 protein-altering or splice-affecting, 10 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 10, Intron 3, Splice Site 3, Nonsense Mutation 3, Splice Region 2, 5'UTR 1, 5'Flank 1, In Frame Del 1, RNA 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1333-2A>G p.X445_splice | Splice Site (SNP) | VAF 41/125 reads (33%) | hotspot (GDC flag); catalogued as rs1555286503, CS030552, COSV57301529, COSV57304999, COSV57326295; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AHNAK | c.8104A>G p.I2702V | Missense Mutation (SNP) | VAF 11/209 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.076); catalogued as COSV57224790, COSV57229143; called by muse, mutect2
- ANO4 | c.659T>A p.L220Q (on ENST00000392977 / NM_001286615.2; = p.L185Q on NM_178826.4) | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV54588003, COSV54607175; called by muse, mutect2, varscan2
- ANXA4 | c.26C>T p.T9I | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs1559195335, COSV67849318; called by muse, mutect2
- ARMT1 | c.1159C>G p.Q387E | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV66178938; called by muse, mutect2, varscan2
- ATP13A3 | c.1277T>G p.I426S | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as COSV55468103; called by muse, mutect2
- BAZ2A | c.4925G>T p.R1642L | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.302); catalogued as COSV51631385, COSV51641212; called by muse, mutect2, varscan2
- BRDT | c.346G>T p.V116F | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62866542; called by muse, mutect2, varscan2
- BTNL3 | c.1352A>C p.D451A | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs763156873, COSV61565456; called by muse, mutect2, varscan2
- CCDC136 | c.1646A>T p.K549M | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.121); catalogued as COSV52803107; called by muse, mutect2, varscan2
- CD163L1 | c.3887T>C p.L1296P | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.105); catalogued as COSV58021771; called by mutect2, varscan2
- CEBPZ | c.692C>G p.S231C | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV50017233; called by muse, mutect2, varscan2
- CENPJ | c.3196G>T p.E1066* | Nonsense Mutation (SNP) | VAF 40/154 reads (26%) | catalogued as COSV67883975; called by muse, mutect2, varscan2
- COL7A1 | c.7068+3G>T | Splice Region (SNP) | VAF 21/77 reads (27%) | catalogued as COSV100097156; called by muse, mutect2, varscan2
- CSNK1A1L | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 83/244 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.035); catalogued as rs201851808, COSV65789708; called by muse, mutect2, varscan2
- DYDC1 | c.383A>G p.D128G | Missense Mutation (SNP) | VAF 28/286 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs765074618, COSV64731834; called by muse, mutect2
- EGFLAM | c.1023G>T p.R341S | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV59312453; called by muse, mutect2, varscan2
- FAM13B | c.1942G>A p.G648S | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV50370662; called by muse, mutect2, varscan2
- FAM160B2 | c.1860C>A p.S620R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.449); catalogued as COSV57159956; called by muse, mutect2, varscan2
- FAT3 | c.5138T>A p.I1713N | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV53154672; called by muse, mutect2, varscan2
- GATA6 | c.1727C>T p.S576L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV52527102; called by muse, mutect2, varscan2
- GH2 | c.503C>A p.S168Y | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV100236793, COSV60427496; called by muse, mutect2, varscan2
- GLUD2 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 90/354 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.118); catalogued as COSV60151647, COSV60152693, COSV60152984; called by muse, mutect2, varscan2
- GPR63 | c.367C>A p.L123I | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV57742771; called by muse, mutect2, varscan2
- HSPG2 | c.8218G>A p.E2740K | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as rs545072429, COSV65974972; called by mutect2, varscan2
- ITGA1 | c.2987C>T p.P996L | Missense Mutation (SNP) | VAF 70/185 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV50892031; called by muse, mutect2, varscan2
- KCNF1 | c.935C>T p.T312I | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1408325931, COSV54464904; called by muse, mutect2, varscan2
- LRFN5 | c.755G>A p.R252K | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV53269466; called by muse, mutect2, varscan2
- LY75 | c.1353G>T p.E451D | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV55110907; called by muse, mutect2, varscan2
- LY75 | c.1352A>T p.E451V | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55110918; called by muse, mutect2, varscan2
- MAN1A1 | c.1363G>A p.G455R | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754857944, COSV63787073, COSV63788133; called by muse, mutect2, varscan2
- MAN1A2 | c.1255G>T p.A419S | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV62980291, COSV62980614; called by muse, mutect2, varscan2
- MTMR7 | c.701A>G p.D234G | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as rs1265697953, COSV51669142; called by muse, mutect2, varscan2
- NEK11 | c.431T>C p.L144P | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63582924; called by muse, mutect2
- NKAPD1 | c.842C>T p.T281I (on ENST00000280352 / NM_001082970.2; = p.T282I on NM_018195.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV54779379; called by muse, mutect2, varscan2
- OR2G2 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 83/348 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs759345162, COSV60739426, COSV60741596; called by muse, mutect2, varscan2
- OR8D1 | c.26C>A p.A9E | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV63442837; called by muse, mutect2, varscan2
- PCSK6 | c.1292C>A p.A431D | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867715844, COSV59343615; called by muse, mutect2, varscan2
- PDGFB | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 11/72 reads (15%) | catalogued as COSV58646102, COSV58649152; called by muse, mutect2, varscan2
- PGBD1 | c.1170G>C p.W390C | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs143874020; called by muse, mutect2, varscan2
- PIP4P1 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV51658483; called by muse, mutect2, varscan2
- PPP6R3 | c.1326A>C p.E442D (on ENST00000393800 / NM_001352375.2; = p.E391D on NM_018312.5) | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as COSV55733155; called by muse, mutect2, varscan2
- PRUNE2 | c.2168C>A p.P723H | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV65045412; called by muse, mutect2
- PTPRQ | c.4999G>C p.E1667Q (on ENST00000616559; = p.E1625Q on NM_001145026.2) | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as COSV57048335; called by muse, mutect2, varscan2
- QPCTL | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as rs760294625, COSV50004561; called by muse, mutect2, varscan2
- RAD51 | c.99A>G p.I33M | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV51113065; called by muse, varscan2
- RELCH | c.2914G>A p.G972S | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.555); catalogued as COSV56884575, COSV56889757; called by muse, mutect2
- RGPD4 | c.4504A>G p.R1502G | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs776093657; called by muse, mutect2, varscan2
- RIC1 | c.1006T>G p.F336V | Missense Mutation (SNP) | VAF 105/299 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV52613489; called by muse, mutect2, varscan2
- RNF20 | c.1896A>T p.E632D | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.06); catalogued as COSV66661985; called by muse, mutect2, varscan2
- RPS3 | c.11A>G p.Q4R | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs772964979, COSV53705317; called by muse, mutect2, varscan2
- SCN3B | c.365T>A p.V122E | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV54800659; called by muse, mutect2, varscan2
- SELL | c.929G>T p.G310V (on ENST00000650983; = p.G297V on NM_000655.5) | Missense Mutation (SNP) | VAF 13/214 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52552888; called by muse, mutect2
- SIGLEC8 | c.1237G>T p.A413S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.085); catalogued as COSV58475201; called by muse, mutect2, varscan2
- SLC38A7 | c.938C>A p.S313Y | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54704301; called by muse, mutect2, varscan2
- SYCP1 | c.329A>G p.Y110C | Missense Mutation (SNP) | VAF 87/194 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557748720, COSV65700039; called by muse, mutect2, varscan2
- THSD7A | c.2888C>A p.A963E | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV70269904; called by muse, mutect2, varscan2
- TLR8 | c.269C>G p.T90S (on ENST00000218032 / NM_138636.5; = p.T108S on NM_016610.4) | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV54319628; called by muse, mutect2, varscan2
- TMEM106A | c.605A>C p.E202A | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.706); catalogued as COSV59045976; called by muse, mutect2, varscan2
- TNKS2 | c.2662G>A p.E888K | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.532); catalogued as rs556843721, COSV65416425; called by muse, mutect2, varscan2
- UBE2J1 | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1389049746, COSV70562076; called by muse, mutect2
- UBE2N | c.338G>C p.S113T | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.41); catalogued as COSV58868749; called by muse, mutect2, varscan2
- USP4 | c.299C>G p.A100G | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.301); catalogued as COSV55538535, COSV55539467; called by muse, mutect2, varscan2
- VAX1 | c.333G>C p.Q111H | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53330223; called by muse, mutect2, varscan2
- ASXL1 | c.2229_2239del p.G744Pfs*26 | Frame Shift Del (DEL) | VAF 9/69 reads (13%) | called by mutect2, pindel, varscan2
- COL7A1 | c.7068+4A>T | Splice Region (SNP) | VAF 22/77 reads (29%) | called by muse, mutect2, varscan2
- CYTIP | c.546+1G>T p.X182_splice | Splice Site (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- LY6H | c.419C>A p.P140H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); called by muse, mutect2
- NCOR2 | c.5688-27_5695del p.X1896_splice | Splice Site (DEL) | VAF 50/128 reads (39%) | called by mutect2, pindel
- PLEKHM1 | c.34_35insGGTAGGTG p.Q12Rfs*2 | Nonsense Mutation (INS) | VAF 4/50 reads (8%) | called by mutect2, pindel*
- UNC13B | c.4624_4674del p.C1542_G1558del | In Frame Del (DEL) | VAF 20/60 reads (33%) | called by mutect2, pindel
- AC006059.2 | c.1851C>T p.R617= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV59608638; called by mutect2, varscan2
- CEP350 | c.2550C>T p.S850= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as rs776336094, COSV62607795; called by muse, mutect2, varscan2
- DOCK6 | c.2740C>T p.L914= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV53919840; called by muse, mutect2, varscan2
- ECH1 | c.186T>C p.S62= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV55490016; called by muse, mutect2
- FAM124B | c.1284C>T p.T428= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as COSV66273188; called by muse, mutect2
- FCRL3 | c.642G>A p.Q214= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV63841432, COSV63843885; called by muse, mutect2
- KDM4C | c.135T>C p.G45= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as COSV67190443; called by muse, mutect2, varscan2
- KDSR | c.537A>C p.G179= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV58507679; called by muse, mutect2, varscan2
- SNCAIP | c.1200C>T p.C400= | Silent (SNP) | VAF 35/137 reads (26%) | catalogued as rs772706842, COSV54417636; called by muse, mutect2, varscan2
- SPATA20 | c.1785G>A p.A595= (on ENST00000356488 / NM_001258372.1; = p.A611= on NM_022827.4) | Silent (SNP) | VAF 19/109 reads (17%) | catalogued as rs746708709, COSV50066405; called by muse, mutect2, varscan2
- DALRD3 | chr3:49020176 C>T | 5'Flank (SNP) | VAF 8/35 reads (23%) | catalogued as COSV100455225, COSV58246734; called by muse, mutect2, varscan2
- ENAH | c.803-610C>T | Intron (SNP) | VAF 10/35 reads (29%) | catalogued as rs1451558038; called by muse, mutect2, varscan2
- GUCY1B2 | n.1514A>G | RNA (SNP) | VAF 11/80 reads (14%) | called by muse, varscan2
- MAGEB18 | c.*16C>A | 3'UTR (SNP) | VAF 24/73 reads (33%) | catalogued as COSV100305578; called by muse, mutect2, varscan2
- MGST3 | c.-104+967G>A | Intron (SNP) | VAF 17/128 reads (13%) | catalogued as rs377067925; called by muse, mutect2, varscan2
- NAA20 | c.53+608T>C | Intron (SNP) | VAF 33/91 reads (36%) | called by muse, mutect2, varscan2
- TSTD1 | c.-71G>A | 5'UTR (SNP) | VAF 7/55 reads (13%) | catalogued as COSV104390079, COSV99231212; called by muse, mutect2, varscan2
